Gene-level copy-number profile of tumor specimen TCGA-02-0023-01B from TCGA case TCGA-02-0023, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 38.3 years (14,003 days).
Specimen TCGA-02-0023-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.6e7865eb-85de-4ff0-b153-96775aa95186.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0023-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53505df4-765d-4e38-8563-1cff82380d76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 5,797; copy number 2: 49,591; copy number 3: 4,325; copy number 5: 8; copy number 28: 4; copy number 30: 23; copy number 32: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0023-01): tumor purity 0.78, ploidy 1.96, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,384,255–24,088,051, 47 genes: IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr10:127,549,309–128,320,214, 12 genes: NPS, AL391005.1, FOXI2, BUB1P1, CLRN3, PTPRE, AL158166.2, AL158166.1, AL390236.1, MKI67, LINC01163, AL390763.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:50,093,279–50,262,994, 4 genes, copy number 28 (within-gene range 2–28): AC034148.1, SPATA48, AC020743.1, AC020743.2.
- chr7:51,382,284–52,269,569, 11 genes, copy number 32: CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1.
- chr7:53,490,148–55,572,988, 31 genes, copy number 5–30 (within-gene range 2–30): RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.

Autosomal genes at a single copy (total copy number 1): 5,747. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
